Somatic mutation profile of tumor specimen TARGET-15-SJMPAL012420-09A.1 (aliquot TARGET-15-SJMPAL012420-09A.1-01D) from TARGET case TARGET-15-SJMPAL012420, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (1,001 days).
Specimen TARGET-15-SJMPAL012420-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25f3233c-2c0f-4029-a7d0-d3c3fa70bbac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL012420-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL012420-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/adb13c5d-bf55-4886-8c19-6015e465217f

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS7 | c.1804G>A p.V602I | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1242657817, COSV66306657; called by muse, mutect2
- GON4L | c.452C>T p.T151I | Missense Mutation (SNP) | VAF 98/218 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1408890506, COSV55206859; called by muse, varscan2
- IZUMO2 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.421); catalogued as COSV53229360; called by muse, mutect2
- MUC4 | c.7815G>C p.Q2605H | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.224); catalogued as rs368501323; called by muse, varscan2
- NCOA3 | c.3563G>A p.R1188Q | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs774124954, COSV59067343; called by muse, mutect2, varscan2
- FAM230G | n.238-727A>G | Intron (SNP) | VAF 26/158 reads (16%) | catalogued as rs586806; called by muse, mutect2, varscan2
